Somatic mutation profile of tumor specimen TCGA-D8-A1X5-01A (aliquot TCGA-D8-A1X5-01A-11D-A14G-09) from TCGA case TCGA-D8-A1X5, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 81.4 years (29,734 days).
Specimen TCGA-D8-A1X5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f19aa74c-5f54-417b-b8bb-b2a79a8acd8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1X5-10A (Blood Derived Normal), aliquot TCGA-D8-A1X5-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e31cf10-5db5-4b67-b7b1-a30d33a76c5b

The open-access MAF lists 54 somatic variants for this specimen: 37 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 29, Silent 17, Frame Shift Ins 4, Nonsense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 15/27 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANO10 | c.1564G>T p.A522S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV52734789; called by muse, mutect2, varscan2
- APOB | c.4834T>C p.F1612L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV51946405; called by muse, mutect2, varscan2
- BNIPL | c.985C>A p.L329M | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54848271; called by muse, mutect2, varscan2
- C1RL | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1226806772, COSV99864862; called by muse, mutect2
- CDKL5 | c.2332G>T p.G778* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV66112620; called by mutect2, varscan2
- COL22A1 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.656); catalogued as rs551462454, COSV57328237; called by muse, mutect2, varscan2
- CTTNBP2 | c.1037G>T p.C346F | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV50444348; called by muse, mutect2, varscan2
- DERA | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV70775060; called by muse, mutect2, varscan2
- DSP | c.5437G>C p.E1813Q | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.702); catalogued as COSV65794501; called by muse, mutect2, varscan2
- EN1 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54632260; called by muse, mutect2, varscan2
- FMN2 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV100145081, COSV60415433, COSV99070470; called by muse, mutect2
- INMT | c.743C>A p.A248D | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1038528116, COSV50002163; called by muse, mutect2, varscan2
- KIAA2026 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV67356884; called by muse, mutect2, varscan2
- LAMB2 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV59735315; called by muse, mutect2, varscan2
- LRRC36 | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as COSV99338989; called by muse, mutect2, varscan2
- MAP2 | c.3718G>T p.E1240* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV52288151, COSV52302510; called by muse, mutect2, varscan2
- MS4A14 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV55736930; called by muse, mutect2, varscan2
- MYH13 | c.4223C>T p.T1408M | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as rs373425936; called by muse, mutect2, varscan2
- MYO6 | c.774_775insTA p.I259* | Frame Shift Ins (INS) | VAF 16/105 reads (15%) | catalogued as COSV64120547; called by mutect2, pindel, varscan2
- PGBD1 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as COSV52555258; called by mutect2, varscan2
- POC1A | c.1178A>C p.Q393P | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV56592884; called by muse, mutect2, varscan2
- PRPF4 | c.247G>T p.A83S (on ENST00000374198 / NM_001322267.2; = p.A84S on NM_004697.5) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.017); catalogued as COSV100950743, COSV65253466; called by muse, mutect2
- RAB9B | c.26A>C p.K9T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54588098; called by muse, mutect2, varscan2
- RBM25 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1167265695, COSV56202815; called by muse, mutect2
- RNF182 | c.573G>T p.L191F | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.994); catalogued as COSV70369799; called by muse, mutect2, varscan2
- ROR2 | c.2468G>C p.G823A | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100996004; called by muse, mutect2
- RUBCN | c.781A>G p.S261G | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99584703; called by muse, mutect2
- SLC26A7 | c.1287dup p.Y430Ifs*6 | Frame Shift Ins (INS) | VAF 16/106 reads (15%) | catalogued as rs1453046666; called by mutect2, varscan2
- SLC8A1 | c.1352C>A p.A451E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60491982; called by muse, mutect2
- SNX19 | c.1727A>G p.Y576C | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV56287856; called by muse, mutect2, varscan2
- STAG2 | c.1678A>T p.R560W | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV54368110; called by muse, mutect2, varscan2
- TMEM200A | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as COSV99759722; called by muse, mutect2
- ZP4 | c.484G>T p.G162* | Nonsense Mutation (SNP) | VAF 10/83 reads (12%) | catalogued as COSV63911761; called by muse, mutect2, varscan2
- ACACA | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); called by muse, varscan2
- MAP1B | c.3814dup p.L1272Pfs*3 | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- USH2A | c.5736dup p.E1913Rfs*24 | Frame Shift Ins (INS) | VAF 11/81 reads (14%) | called by mutect2, pindel, varscan2
- ACACA | c.150G>C p.L50= | Silent (SNP) | VAF 8/46 reads (17%) | called by muse, varscan2
- APOL6 | c.591G>A p.L197= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV68749664; called by muse, mutect2, varscan2
- C7 | c.1557A>G p.R519= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as rs1319815594, COSV57478375; called by muse, mutect2, varscan2
- CNNM3 | c.2082C>T p.G694= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs755469061, COSV59708911, COSV59709730; called by muse, mutect2, varscan2
- FAM149A | c.1314C>T p.L438= (on ENST00000356371 / NM_001367768.2; = p.L147= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs1347089132, COSV57029485; called by muse, mutect2, varscan2
- FAM160A2 | c.2727C>T p.G909= (on ENST00000449352 / NM_001098794.2; = p.G923= on NM_032127.4) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs778451280, COSV56411442; called by muse, mutect2, varscan2
- FYN | c.1050A>G p.L350= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV57616387, COSV57618591; called by muse, mutect2, varscan2
- GRIK2 | c.18G>A p.P6= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs776282459, COSV100025489, COSV59758434; called by muse, mutect2, varscan2
- PI16 | c.48A>G p.L16= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs1179873856, COSV65448528; called by muse, mutect2, varscan2
- PLB1 | c.1122C>T p.D374= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs773612315, COSV59832539; called by muse, mutect2, varscan2
- TMX3 | c.714C>A p.L238= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV55186902; called by muse, mutect2, varscan2
- TSEN54 | c.1558T>C p.L520= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV51386571; called by muse, mutect2, varscan2
- UNC13B | c.657G>A p.P219= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as rs758755780, COSV65937316; called by muse, mutect2, varscan2
- YTHDF1 | c.303C>T p.H101= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs1480161354, COSV64833655; called by muse, mutect2, varscan2
- ZFP36L2 | c.21C>T p.S7= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs902996805, COSV56699492; called by muse, mutect2, varscan2
- ZNF233 | c.1845G>A p.T615= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs751008846, COSV100492465, COSV61934325; called by muse, mutect2, varscan2
- ZNF574 | c.726C>T p.P242= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs138408881; called by muse, mutect2
